Somatic mutation profile of tumor specimen TCGA-N9-A4Q7-01A (aliquot TCGA-N9-A4Q7-01A-11D-A28R-08) from TCGA case TCGA-N9-A4Q7, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 69.6 years (25,419 days).
Specimen TCGA-N9-A4Q7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e68f4b-7a8a-4d04-9c47-26e840799dd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4Q7-10B (Blood Derived Normal), aliquot TCGA-N9-A4Q7-10B-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b2b2c47-f1d8-4c5b-91a2-16214a8060b9

The open-access MAF lists 287 somatic variants for this specimen: 225 protein-altering or splice-affecting, 57 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 57, Nonsense Mutation 16, Splice Site 6, RNA 2, 3'Flank 1, Frame Shift Del 1, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 53/130 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs1390769718, COSV57863600; called by muse, mutect2, varscan2
- ANKS1A | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64461568; called by muse, mutect2, varscan2
- AP3M1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs751432900, COSV53015672; called by muse, mutect2, varscan2
- ATP6AP1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1557197509, COSV100870699; called by muse, mutect2, varscan2
- BRWD1 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406282052, COSV60899182; called by muse, mutect2
- C1QTNF9 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as rs765808720; called by muse, mutect2, varscan2
- C2orf16 | c.4427G>C p.R1476T | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1558458871, COSV62674547; called by muse, mutect2, varscan2
- CAPN11 | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV67237622; called by muse, mutect2, varscan2
- CDK5RAP3 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs758964348; called by muse, mutect2, varscan2
- CIBAR1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs759944744; called by mutect2, varscan2
- CLCN1 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV58370677, COSV58372294, COSV58375171; called by muse, mutect2, varscan2
- CNPY4 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1323712546; called by muse, mutect2, varscan2
- CTU2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760324933; called by muse, mutect2, varscan2
- DBNDD2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV61918908; called by muse, mutect2
- DCC | c.3061C>G p.R1021G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59103256; called by muse, mutect2, varscan2
- DGKA | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 29/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59387212; called by muse, mutect2
- DPP10 | c.1626C>G p.D542E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100057153; called by muse, mutect2
- EGR2 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54349217; called by muse, mutect2
- ELAVL2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56361675; called by muse, mutect2, varscan2
- ESRP1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412226; called by muse, mutect2, varscan2
- F8 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421760987, CM1314837; called by muse, mutect2, varscan2
- F9 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as CM045763; called by muse, mutect2
- FAM53C | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1292595548; called by muse, mutect2, varscan2
- FANCM | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs986973025; called by muse, mutect2, varscan2
- FNIP1 | c.3095C>G p.S1032C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as rs756406723; called by muse, mutect2, varscan2
- FRMPD4 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66217812; called by muse, mutect2, varscan2
- GPAT2 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | catalogued as rs749442677; called by muse, mutect2
- GRN | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs1369364024, COSV50009043; called by muse, mutect2, varscan2
- H1-7 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs769658441; called by muse, mutect2, varscan2
- HDAC7 | c.1064G>A p.R355Q (on ENST00000427332; = p.R394Q on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50324553; called by muse, mutect2, varscan2
- HMCN1 | c.6142G>C p.D2048H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54907991; called by muse, mutect2, varscan2
- IDE | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs188992947; called by mutect2, varscan2
- IGFLR1 | c.158-1G>C p.X53_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | catalogued as COSV53075998; called by muse, mutect2
- IGSF9B | c.3832C>A p.L1278M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.36); catalogued as COSV58063842; called by muse, mutect2, varscan2
- IL4I1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763738158, COSV55580240; called by muse, mutect2, varscan2
- INPP5A | c.903G>A p.A301= | Splice Region (SNP) | VAF 17/102 reads (17%) | catalogued as rs142848612; called by muse, mutect2, varscan2
- INTS13 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs757073411; called by muse, mutect2
- JCAD | c.1850C>A p.P617Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as COSV100948468; called by muse, mutect2, varscan2
- KAT7 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs375311893, COSV52013622; called by muse, mutect2
- LRP2 | c.7493C>T p.S2498F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs142613860; called by muse, mutect2, varscan2
- LRRN1 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV60016208; called by muse, mutect2
- MACF1 | c.20518G>A p.D6840N (on ENST00000372915; = p.D4885N on NM_012090.5) | Missense Mutation (SNP) | VAF 102/317 reads (32%) | catalogued as rs769550602, COSV57129886, COSV57137881; called by muse, mutect2, varscan2
- MAEA | c.959C>T p.S320F (on ENST00000303400 / NM_001017405.3; = p.S279F on NM_005882.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs1411876634; called by muse, mutect2, varscan2
- MAP3K15 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as rs370173616, COSV100135461; called by muse, mutect2, varscan2
- MGAT4A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.354); catalogued as rs1240095022, COSV53850733; called by muse, mutect2
- MRPS7 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 49/486 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs755782422; called by muse, mutect2, varscan2
- MST1 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1478536428; called by mutect2, varscan2
- MYORG | c.747G>C p.W249C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs1356560096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAGLU | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs368687817, CM981362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.4105C>T p.R1369W | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs752297905, COSV73187908; called by muse, mutect2
- NPC1L1 | c.2512C>G p.P838A | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56930694; called by muse, mutect2, varscan2
- OR10G7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs779903828, COSV57869277; called by muse, mutect2, varscan2
- OR10K1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56873308; called by muse, mutect2
- OR10X1 | c.610T>C p.S204P | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1047369186; called by muse, mutect2
- OR4C16 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV58943318; called by muse, mutect2
- OTOF | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs111033535; ClinVar: uncertain significance; called by mutect2, varscan2
- P2RY10 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs866124188, COSV50682005, COSV50686293; called by muse, mutect2
- PBRM1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs774655494, COSV56294959, COSV56298403; called by muse, mutect2, varscan2
- PCNT | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375046076, COSV100855716; called by mutect2, varscan2
- PELI2 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV50711127; called by muse, mutect2, varscan2
- PJA2 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63271700, COSV63275042; called by muse, mutect2, varscan2
- PLD3 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs752779193, COSV52522413; called by muse, mutect2, varscan2
- PLEKHA8 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV51653865; called by muse, mutect2
- PLS3 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56780145; called by muse, mutect2, varscan2
- PNLIPRP1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62612608; called by muse, mutect2, varscan2
- PPP2R1A | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59045522; called by muse, mutect2, varscan2
- PRKAR1A | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV62236041; called by muse, mutect2, varscan2
- PRR5L | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.995); catalogued as rs1298382405; called by muse, mutect2, varscan2
- PTPRM | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1160490933; called by muse, mutect2, varscan2
- PTPRZ1 | c.3183G>C p.E1061D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV66439544; called by muse, mutect2, varscan2
- RAC1 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61821797, COSV61822724; called by muse, mutect2, varscan2
- RAD52 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1468241010; called by muse, mutect2
- RALGAPB | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs1033847127; called by muse, mutect2, varscan2
- RASA1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs532587037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF111 | c.2164C>A p.Q722K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1369662132, COSV62087631; called by muse, mutect2, varscan2
- RNF43 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV60414909, COSV60416798, COSV60417997, COSV60418425; called by muse, mutect2
- RUSC2 | c.3730G>C p.E1244Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.109); catalogued as rs753880307, COSV63429522; called by muse, mutect2, varscan2
- SDE2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979841467, COSV55251965; called by muse, mutect2
- SDK1 | c.2203C>G p.P735A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1182214342; called by muse, mutect2, varscan2
- SEPTIN2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV100764896; called by muse, mutect2
- SFRP4 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71412340; called by muse, mutect2, varscan2
- SLC8A3 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs76086886, COSV63526024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.4949G>C p.R1650T (on ENST00000392056 / NM_001142644.2; = p.R1621T on NM_030623.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60883815; called by muse, mutect2
- SPON2 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV52054763; called by muse, mutect2, varscan2
- SULF2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.574); catalogued as rs1308129487; called by muse, mutect2, varscan2
- SYNDIG1 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV65232542; called by muse, mutect2
- TBC1D9 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV71308104; called by muse, mutect2
- TECPR2 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773608997, COSV63972141; called by muse, mutect2, varscan2
- TECR | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV53108588; called by muse, mutect2, varscan2
- TMUB2 | c.172G>A p.V58I (on ENST00000538716 / NM_001353177.2; = p.V38I on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1445423734; called by muse, mutect2, varscan2
- TRA2A | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1428325822, COSV51716787; called by muse, mutect2
- TRHDE | c.2107G>C p.D703H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV53839607; called by muse, mutect2, varscan2
- TSGA13 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV58404451; called by muse, mutect2, varscan2
- TTN | c.9245C>T p.S3082F (on ENST00000591111; = p.S3036F on NM_003319.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV59890360; called by muse, mutect2, varscan2
- UNC119 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930130211; called by muse, mutect2, varscan2
- VSX2 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767248901, COSV56217948; called by mutect2, varscan2
- VWF | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs146892641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR35 | c.3160C>T p.H1054Y (on ENST00000345530 / NM_001006657.2; = p.H1043Y on NM_020779.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as COSV55601503; called by muse, mutect2, varscan2
- ZBTB11 | c.3026C>G p.S1009C | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1306180119, COSV104397942; called by muse, mutect2
- ZDBF2 | c.3982G>C p.E1328Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as rs1352390124; called by muse, mutect2
- ZMAT3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs893943065; called by muse, mutect2, varscan2
- ABCA12 | c.3916G>C p.E1306Q (on ENST00000272895 / NM_173076.3; = p.E988Q on NM_015657.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); called by mutect2, varscan2
- ABCA2 | c.3547G>C p.G1183R (on ENST00000614293; = p.G1153R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ACACA | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGA | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ALDH6A1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANGPTL1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- AP001781.2 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ASTN1 | c.3418A>C p.I1140L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8B3 | c.1710C>G p.I570M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ATXN2 | c.1067C>G p.S356C (on ENST00000550104; = p.S196C on NM_002973.4) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- C2CD3 | c.629C>G p.S210* | Nonsense Mutation (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- CACNA1H | c.4543G>C p.D1515H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CBARP | c.632C>G p.S211* (on ENST00000382477; = p.S191* on NM_152769.3) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- CCT3 | c.1056C>G p.I352M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2
- CHD9 | c.6685G>A p.E2229K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- CNKSR2 | c.1394-1G>C p.X465_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- CNMD | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- COG4 | c.370-1G>A p.X124_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- COL4A5 | c.1327C>G p.H443D | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, mutect2
- COPB1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- CP | c.2526G>C p.E842D | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- CPXM1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRBN | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCLRE1A | c.1950G>C p.Q650H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- DNAH5 | c.10765C>G p.Q3589E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DUOX1 | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- EBF2 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- EIF1 | c.32-1G>C p.X11_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- EIF3B | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- EIF4H | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- EPB41L2 | c.3004G>C p.E1002Q | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOC3 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- FANCM | c.5602C>G p.Q1868E | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FER1L6 | c.3329-1G>T p.X1110_splice | Splice Site (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- GABRA4 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.023); called by muse, mutect2
- GNAI3 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- GOLGB1 | c.4795G>A p.A1599T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GTF3C2 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HCFC1 | c.5141C>T p.T1714I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HDGFL3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HFM1 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- HHIP | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- HIVEP3 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- HSPA4L | c.1710G>C p.Q570H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- HVCN1 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IFI44 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.917); called by muse, mutect2
- IL1R1 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IQGAP2 | c.4393G>C p.D1465H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ITSN2 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCTD1 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KDM6B | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- KHDC4 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KIAA0753 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- L3MBTL3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHCGR | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEA10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAN1B1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MKI67 | c.9192G>C p.E3064D | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- MPDZ | c.5108G>C p.R1703T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MYH9 | c.2550G>T p.K850N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MYO5C | c.3745C>G p.Q1249E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYSM1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); called by muse, mutect2
- NEFH | c.2932G>T p.D978Y | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- OLAH | c.689T>C p.I230T (on ENST00000378228 / NM_001039702.3; = p.I283T on NM_018324.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- OR4K5 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2
- OR6C6 | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- ORC3 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- PCDHA3 | c.1703C>A p.P568H | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PCNT | c.5218G>C p.E1740Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDZD8 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PGBD5 | c.1242C>G p.I414M (on ENST00000525115; = p.I483M on NM_001258311.2) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PKDREJ | c.6139G>C p.D2047H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCB3 | c.3224C>G p.A1075G | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2
- POF1B | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- PREX2 | c.4373C>T p.S1458L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCE | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRPF8 | c.4819G>C p.E1607Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- PRRC2A | c.6123C>G p.F2041L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.931); called by muse, mutect2
- PRRT1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPN3 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.262); called by muse, mutect2
- RO60 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RSF1 | c.1431C>A p.D477E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2
- RSKR | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- RUSC2 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SEMA6D | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SERHL2 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- SLCO1C1 | c.2009C>G p.S670* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SLITRK5 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLU7 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMARCA5 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SORCS1 | c.2434G>T p.E812* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- SPAG17 | c.1497+1G>T p.X499_splice | Splice Site (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- SPG11 | c.5788G>A p.E1930K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- STAMBPL1 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STK10 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- STXBP5L | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TCF20 | c.3863C>G p.S1288* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- TFAP2E | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TGM4 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TICRR | c.4076C>G p.S1359* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- TIMELESS | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLR2 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMEM123 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TMEM155 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM43 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2
- TNPO3 | c.2444_2445del p.F815* | Frame Shift Del (DEL) | VAF 44/225 reads (20%) | called by mutect2, pindel, varscan2
- TNXB | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAK2 | c.2544G>C p.K848N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSPAN10 | c.920C>A p.A307E (on ENST00000574882 / NM_001290212.1; = p.A269E on NM_031945.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.331); called by muse, mutect2
- TTN | c.89587C>G p.Q29863E (on ENST00000591111; = p.Q22439E on NM_003319.4) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- UBP1 | c.705T>G p.F235L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- UBXN1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.326); called by muse, mutect2
- VNN2 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- WASHC2A | c.4016G>A p.G1339E | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.7475C>G p.S2492C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- WRN | c.2916C>G p.I972M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- YARS1 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- YPEL4 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFP82 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ZNF513 | c.1108C>G p.H370D | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF610 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS16 | c.3279G>A p.K1093= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV56984260; called by muse, mutect2, varscan2
- APC2 | c.1515C>G p.L505= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52016873; called by muse, mutect2, varscan2
- BTNL8 | c.750C>T p.G250= | Silent (SNP) | VAF 29/267 reads (11%) | catalogued as rs1322989540; called by muse, mutect2, varscan2
- CCNI | c.795C>T p.L265= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- CDC42EP2 | c.357C>T p.L119= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- CHRND | c.480C>T p.F160= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs200986300, COSV51331646; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CPNE2 | c.1323C>T p.I441= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- DHCR24 | c.354G>C p.L118= | Silent (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- DISP3 | c.3042C>G p.V1014= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- DNAH2 | c.2031C>T p.L677= | Silent (SNP) | VAF 27/270 reads (10%) | catalogued as rs1190853317; called by muse, mutect2, varscan2
- DSP | c.1740A>T p.I580= | Silent (SNP) | VAF 29/320 reads (9%) | called by muse, mutect2
- ESRRB | c.435C>T p.C145= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1064439; called by muse, mutect2
- FGFR4 | c.765C>T p.L255= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1287800483; called by muse, mutect2, varscan2
- FLNA | c.843G>A p.P281= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs782070351, COSV61048392; called by muse, mutect2, varscan2
- GABRA2 | c.1089G>A p.Q363= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- GNG5 | c.192C>G p.V64= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- HEATR5B | c.1473C>G p.L491= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV51853863; called by muse, mutect2, varscan2
- HEPH | c.3216C>T p.L1072= (on ENST00000343002; = p.L805= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- HPS6 | c.651C>G p.L217= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- IRS1 | c.867C>G p.L289= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- KCNA3 | c.945C>T p.F315= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV63902375; called by muse, mutect2, varscan2
- LRRC15 | c.1333T>C p.L445= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1234109754, COSV61650813; called by muse, mutect2
- MAD1L1 | c.1065C>T p.V355= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2, varscan2
- MEOX2 | c.327C>T p.C109= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1366288202; called by muse, mutect2
- MGA | c.3684C>T p.V1228= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1478256028, COSV54963131; called by muse, mutect2
- MUC21 | c.1356G>A p.L452= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- NAV3 | c.1182G>T p.R394= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV57065957, COSV99893341; called by muse, mutect2
- NOLC1 | c.2073C>T p.V691= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as COSV100893761; called by muse, mutect2, varscan2
- NOSIP | c.591G>A p.L197= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1367407265; called by muse, mutect2
- OR2T34 | c.537C>T p.I179= | Silent (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- P2RX7 | c.96C>T p.F32= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- PAPPA2 | c.57C>G p.L19= | Silent (SNP) | VAF 9/179 reads (5%) | called by muse, mutect2
- PCSK7 | c.1311C>T p.F437= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV58009457; called by muse, mutect2, varscan2
- PEX12 | c.99G>A p.V33= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- PI4KA | c.4911C>T p.Y1637= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs746070245; called by muse, mutect2, varscan2
- PIP5K1C | c.597G>A p.Q199= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs777175094; called by muse, mutect2, varscan2
- PLEKHJ1 | c.449G>A p.*150= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- PTPN13 | c.6519G>C p.L2173= (on ENST00000411767 / NM_080683.3; = p.L2154= on NM_006264.3) | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- RIN2 | c.1677G>A p.P559= (on ENST00000255006 / NM_001242581.1; = p.P510= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as rs755250708; called by muse, mutect2, varscan2
- RNF128 | c.1080G>A p.E360= (on ENST00000255499 / NM_194463.2; = p.E334= on NM_024539.3) | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- RRP36 | c.687G>C p.L229= | Silent (SNP) | VAF 23/287 reads (8%) | called by muse, mutect2
- SDF4 | c.999C>G p.L333= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1044071774; called by muse, mutect2, varscan2
- SERPINB7 | c.642C>T p.F214= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs368022993; called by muse, mutect2, varscan2
- SLC35B2 | c.84G>T p.P28= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- SLC35E4 | c.951C>T p.L317= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SMARCC2 | c.1701G>A p.E567= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- SOAT1 | c.1590G>A p.L530= | Silent (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2
- SORL1 | c.1443C>T p.L481= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- SPSB2 | c.336C>A p.L112= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV51290481; called by muse, mutect2
- STAT1 | c.1710C>A p.L570= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- SYMPK | c.1938C>T p.L646= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs1437191593, COSV55610769; called by muse, mutect2, varscan2
- TAF6L | c.813C>G p.L271= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as rs1225393355; called by muse, mutect2, varscan2
- TEX2 | c.114C>T p.F38= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- YOD1 | c.504C>T p.V168= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- ZNF649 | c.1164A>G p.G388= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- ZNF80 | c.21G>A p.G7= | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- ZNF821 | c.381C>T p.C127= (on ENST00000425432 / NM_001376297.1; = p.C85= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs189263731, COSV100546832; called by muse, mutect2, varscan2
- CDK20 | c.*374G>C | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- OR2U1P | n.232C>G | RNA (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948534 C>A | 3'Flank (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99989202; called by muse, mutect2, varscan2
- PRDM15 | c.-501G>C | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ZNF658B | n.1035C>G | RNA (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
